Gene-level copy-number profile of specimen HCM-WCMC-1287-C67-85A from HCMI case HCM-WCMC-1287-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Combined small cell carcinoma; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3; Age at diagnosis: 74.8 years (27,327 days).
Specimen HCM-WCMC-1287-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3325d7f4-70a4-4918-8836-8fba56368396.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-1287-C67-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,629 have no estimate.
https://portal.gdc.cancer.gov/files/8d954663-009f-4134-81f8-79c5f1aae69e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 507; copy number 2: 5,860; copy number 3: 38,818; copy number 4: 10,582; copy number 5: 1,292; copy number 6: 477; copy number 7: 92; copy number 8: 43; copy number 9: 29; copy number 10: 34; copy number 11: 45; copy number 12: 18; copy number 13: 4; copy number 14: 52; copy number 15: 4; copy number 16: 3; copy number 17: 5; copy number 18: 3; copy number 19: 64; copy number 21: 4; copy number 22: 2; copy number 23: 1; copy number 24: 2; copy number 25: 3; copy number 26: 1; copy number 27: 2; copy number 29: 4; copy number 36: 1; copy number 43: 1; copy number 52: 15; copy number 67: 1; copy number 69: 6; copy number 82: 2.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:200,404,940–200,410,056, 1 gene: ZNF281.
- chr2:90,052,581–90,053,372, 1 gene: IGKV2D-18.
- chr2:90,114,838–90,122,564, 2 genes (within-gene range 0–2): IGKV3D-15, IGKV2D-14.
- chr2:203,190,780–203,191,277, 1 gene (within-gene range 0–1): RPL12P16.
- chr2:213,266,995–213,276,152, 1 gene: AC079610.2.
- chr2:224,294,930–224,295,753, 1 gene: AC008072.1.
- chr5:29,516,005–29,516,504, 1 gene: AC027345.1.
- chr13:57,391,171–57,391,518, 1 gene: RPL31P53.
- chr14:106,790,691–106,791,233, 1 gene: IGHV3-72.
- chr18:21,817,624–21,817,828, 1 gene (within-gene range 0–3): SNORA73.
- chr21:23,857,081–23,890,541, 2 genes: AP000474.2, AP000474.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 423 genes in 154 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,292,390–1,349,418, 10 genes, copy number 7–8: ACAP3, MIR6726, PUSL1, INTS11, MIR6727, AL139287.1, CPTP, TAS1R3, DVL1, MIR6808.
- chr1:111,437,514–111,449,256, 3 genes, copy number 7–15 (within-gene range 1–15): UBE2FP3, AL390195.1, WDR77.
- chr1:111,448,864–111,478,512, 2 genes, copy number 7–9 (within-gene range 7–15): ATP5PB, C1orf162.
- chr1:121,494,329–121,511,588, 2 genes, copy number 8: AL592494.1, MTIF2P1.
- chr1:207,165,496–207,229,202, 3 genes, copy number 9–17: C4BPAP1, AL445493.2, C4BPAP2.
- chr2:39,664,982–39,779,267, 2 genes, copy number 7 (within-gene range 5–7): TMEM178A, THUMPD2.
- chr2:108,226,015–108,265,351, 2 genes, copy number 7–11: SETD6P1, SULT1C3.
- chr2:168,456,249–168,775,134, 3 genes, copy number 7 (within-gene range 5–8): CERS6, MIR4774, RNU6-766P.
- chr2:176,830,839–176,930,090, 2 genes, copy number 10–36: AC073636.1, RNU6-187P.
- chr2:179,934,401–179,934,538, 2 genes, copy number 9: AC096587.2, AC096587.1.
- chr2:191,678,068–191,820,257, 3 genes, copy number 9–10 (within-gene range 4–10): NABP1, AC114778.1, AC098872.1.
- chr3:112,736,447–112,812,819, 2 genes, copy number 7: LINC02042, CD200R1L-AS1.
- chr3:177,952,327–178,007,779, 2 genes, copy number 9: AC007953.2, RNU6-1120P.
- chr4:74,418,917–74,455,005, 2 genes, copy number 7–10: AC021180.1, AREG.
- chr5:8,618,581–8,620,310, 2 genes, copy number 18: MTND6P2, MTCYBP37.
- chr5:36,485,343–36,588,661, 2 genes, copy number 7–8: RNA5SP181, AC010631.1.
- chr5:51,438,792–51,665,048, 2 genes, copy number 9: AC022433.1, AC091860.2.
- chr6:19,290,319–24,666,930, 55 genes, copy number 10–82: AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL008627.1, MBOAT1, AL158198.1, AL158198.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL031767.1, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1, AL139093.1, SPTLC1P2, AL032822.1, HNRNPA1P58, NRSN1, FO393410.1, DCDC2, KAAG1, RNU6-391P, MRS2, GPLD1, ALDH5A1, KIAA0319, KRT8P43, TDP2.
- chr6:41,072,945–41,101,056, 2 genes, copy number 7 (within-gene range 3–7): NFYA, AL031778.1.
- chr6:51,385,282–51,410,537, 2 genes, copy number 8–19: AL158050.2, AL158050.1.
- chr7:57,628,479–57,645,189, 2 genes, copy number 14 (within-gene range 2–14): AC064862.6, AC064862.7.
- chr7:99,648,194–99,735,196, 4 genes, copy number 7 (within-gene range 7–49): CYP3A5, CYP3A7-CYP3A51P, CYP3A51P, CYP3A7.
- chr8:36,004,316–37,406,724, 19 genes, copy number 7: AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2.
- chr8:95,947,781–101,669,726, 124 genes, copy number 11–19 (broad region; genes not listed).
- chr8:110,334,743–110,556,518, 2 genes, copy number 11–23: AC073023.1, AC090819.1.
- chr11:13,001,090–13,012,119, 2 genes, copy number 8: RASSF10-DT, RASSF10.
- chr11:48,496,348–48,526,971, 3 genes, copy number 7–10: OR4A46P, OR4A40P, OR4A43P.
- chr11:56,848,478–56,927,885, 2 genes, copy number 8: LINC02735, FADS2B.
- chr11:58,189,070–58,216,084, 3 genes, copy number 7–43: OR9Q2, OR1S2, OR1S1.
- chr11:89,700,764–89,704,658, 2 genes, copy number 7: UBTFL10, AP003122.6.
- chr11:90,031,106–90,053,736, 3 genes, copy number 8–9: TRIM49C, AP004607.2, AP004607.4.
- chr11:109,355,085–109,583,907, 3 genes, copy number 8: AP003049.2, C11orf87, AP003049.1.
- chr11:111,089,870–111,179,641, 4 genes, copy number 8–24 (within-gene range 3–24): AP003973.2, LINC02550, AP003973.3, RPS17P15.
- chr12:21,759,980–21,775,600, 2 genes, copy number 8 (within-gene range 3–8): AC010185.1, KCNJ8.
- chr13:79,566,678–79,918,042, 2 genes, copy number 7–10: LINC01068, LINC00382.
- chr16:51,755,325–52,677,747, 17 genes, copy number 9–11: LINC01571, C16orf97, AC009039.1, AC009039.2, LINC00919, LINC02180, AC007333.2, AC007333.1, CASC22, TOX3, AC007490.1, CASC16, AC026462.5, AC026462.3, AC026462.2, AC026462.4, AC026462.1.
- chr17:3,276,942–3,386,317, 2 genes, copy number 8 (within-gene range 2–8): OR3A2, OR3A1.
- chr17:61,069,856–61,070,356, 2 genes, copy number 12 (within-gene range 2–12): AC005884.2, RPL23AP74.
- chr19:1,228,287–1,244,825, 3 genes, copy number 7 (within-gene range 4–7): CBARP, AC004221.1, ATP5F1D.
- chr20:55,997,357–56,205,173, 2 genes, copy number 7–9: CBLN4, RNA5SP487.

Autosomal genes at a single copy (total copy number 1): 465. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
